Gene-level copy-number profile of tumor specimen ALCH-B2R3-TTP1-A from ALCHEMIST case ALCH-B2R3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.8 years (18,910 days).
Specimen ALCH-B2R3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d3d8a594-e9f3-4f66-8dfe-6e90a81662af.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2R3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/bef0ff33-e736-48c3-9c4b-4bd12bade702

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 1,284; copy number 2: 29,069; copy number 3: 15,279; copy number 4: 11,182; copy number 5: 544; copy number 6: 648; copy number 7: 732; copy number 8: 5; copy number 9: 13; copy number 10: 69.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:87,591,607–89,017,059, 35 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1.
- chr10:103,549,075–103,550,964, 1 gene (within-gene range 0–2): AL121929.1.
- chr13:52,497,097–52,500,195, 1 gene: AL137058.3.
- chr15:20,916,686–20,961,581, 3 genes: NF1P1, MIR5701-1, OR11J2P.
- chr16:33,687,025–33,771,248, 3 genes: BMS1P8, ENPP7P13, AC136428.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,558 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,109,404–227,434,346, 97 genes, copy number 5 (broad region; genes not listed).
- chr1:234,356,704–236,764,631, 73 genes, copy number 5 (broad region; genes not listed).
- chr1:244,352,635–248,408,020, 126 genes, copy number 5 (broad region; genes not listed).
- chr6:21,354,411–22,654,455, 10 genes, copy number 5 (within-gene range 4–5): AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1.
- chr6:150,504,811–151,470,101, 24 genes, copy number 5: AL451061.1, PLEKHG1, AL450344.3, AL450344.1, AL450344.2, PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1.
- chr8:13,844,101–14,023,422, 3 genes, copy number 5: AC022690.2, AC022690.1, AC023538.1.
- chr8:37,736,601–41,510,980, 84 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:41,511,240–41,545,044, 3 genes, copy number 7 (within-gene range 2–7): KRT18P37, GINS4, AC009630.2.
- chr8:49,046,652–49,352,844, 5 genes, copy number 7: AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7.
- chr8:94,719,703–102,412,759, 158 genes, copy number 6–7 (broad region; genes not listed).
- chr8:112,222,928–121,119,754, 71 genes, copy number 5–7 (broad region; genes not listed).
- chr8:123,416,726–125,022,283, 39 genes, copy number 6: NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE.
- chr8:139,727,725–145,066,685, 202 genes, copy number 5 (broad region; genes not listed).
- chr13:38,533,343–38,545,299, 1 gene, copy number 5: LINC00437.
- chr13:75,932,395–79,571,445, 50 genes, copy number 6: LINC00561, LINC01034, RN7SL571P, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2, SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, SLAIN1, MIR3665, EDNRB-AS1, EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068.
- chr13:80,654,755–81,691,072, 10 genes, copy number 10: PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr13:98,793,429–99,086,625, 1 gene, copy number 7 (within-gene range 2–7): DOCK9.
- chr13:98,871,742–114,337,626, 232 genes, copy number 7–10 (broad region; genes not listed).
- chr15:20,803,505–20,826,173, 2 genes, copy number 10: AC012414.6, GRAMD4P5.
- chr15:20,890,206–20,901,609, 3 genes, copy number 5: AC012414.5, AC037471.2, ZNF519P2.
- chr15:21,015,048–21,020,851, 2 genes, copy number 5–7: IGHD2OR15-2B, FAM30C.
- chr16:16,760,905–16,762,465, 1 gene, copy number 5: AC092326.1.
- chr16:18,313,294–18,352,476, 5 genes, copy number 8: AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4.
- chr16:32,388,135–32,436,203, 1 gene, copy number 5: AC138915.2.
- chr20:12,243,308–13,169,103, 9 genes, copy number 7: AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1.
- chr20:18,485,265–31,360,930, 203 genes, copy number 7 (broad region; genes not listed).
- chr20:47,656,348–47,786,616, 1 gene, copy number 7 (within-gene range 2–7): SULF2.
- chr20:47,826,969–48,494,309, 16 genes, copy number 7: RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P.
- chr20:52,192,159–59,516,039, 126 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
